Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EB-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9

gt 11/21/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of the cervix:
Invasive squamous cell carcinoma.

Source: NCI Genomic Data Commons file 9476458a-613e-42cd-8795-da408e579d64 (TCGA-VS-A8EB.ED146C1D-315F-4628-A529-62D235938DFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).